Somatic mutation profile of cancer-model specimen HCM-CSHL-0509-C24-85A (3D Organoid, passage 10; aliquot HCM-CSHL-0509-C24-85A-01D-A82H-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0509-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroendocrine carcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 71.8 years (26,219 days).
Specimen HCM-CSHL-0509-C24-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb5ad73c-0541-48d5-b91c-09a3e856458a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0509-C24-11A (Solid Tissue Normal), aliquot HCM-CSHL-0509-C24-11A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bb11b41-addb-4e7e-a388-6416079d7604

The open-access MAF lists 85 somatic variants for this specimen: 61 protein-altering or splice-affecting, 20 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 20, Splice Region 4, Nonsense Mutation 3, Intron 2, In Frame Del 1, Frame Shift Ins 1, In Frame Ins 1, Frame Shift Del 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 274/538 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ACSL6 | c.99G>A p.M33I (on ENST00000379240; = p.M58I on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 236/465 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99734317; called by muse, mutect2, varscan2
- ATP1A3 | c.3022C>T p.R1008C (on ENST00000545399 / NM_001256214.2; = p.R995C on NM_152296.5) | Missense Mutation (SNP) | VAF 205/392 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57485526, COSV57486287; called by muse, varscan2
- ATP2B1 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 394/614 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV99665460; called by muse, mutect2, varscan2
- CAD | c.1906C>T p.P636S | Missense Mutation (SNP) | VAF 161/361 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV53033488; called by muse, mutect2, varscan2
- CDKL5 | c.555C>T p.G185= | Splice Region (SNP) | VAF 152/152 reads (100%) | catalogued as rs904580767, COSV66112914; called by muse, mutect2, varscan2
- CENPP | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 199/454 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781488340; called by muse, varscan2
- DNAH6 | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 182/327 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as rs770563696, COSV52870849; called by muse, mutect2, varscan2
- DSG4 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 351/547 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as COSV57389889; called by muse, mutect2, varscan2
- ESRRB | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 88/861 reads (10%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.062); catalogued as rs773933130; called by muse, mutect2
- FAM170B | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 318/616 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs373146727, COSV61254163; called by muse, varscan2
- FAM184A | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 160/347 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs780653028, COSV58852197; called by muse, mutect2, varscan2
- GRIA1 | c.1160A>C p.K387T | Missense Mutation (SNP) | VAF 122/228 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0.134); catalogued as COSV53589598; called by muse, varscan2
- HEY2 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 341/642 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs113023735, COSV100856409, COSV64240744; called by muse, mutect2, varscan2
- KCNB1 | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 146/310 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65571493; called by muse, varscan2
- LAMA1 | c.2700C>T p.R900= | Splice Region (SNP) | VAF 123/379 reads (32%) | catalogued as rs140067215; called by muse, mutect2, varscan2
- PAOX | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 219/484 reads (45%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs749327396, COSV53372087, COSV99530172; called by muse, mutect2, varscan2
- PCDHA10 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 166/368 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100249716, COSV56532810; called by muse, mutect2, varscan2
- POU2F2 | c.922G>A p.V308I (on ENST00000526816 / NM_001207025.3; = p.V292I on NM_002698.5) | Missense Mutation (SNP) | VAF 199/401 reads (50%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.912); catalogued as rs988567070; called by muse, mutect2, varscan2
- RAB31 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 218/318 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1482555508, COSV71261792; called by muse, mutect2, varscan2
- RAB37 | c.183G>A p.T61= | Splice Region (SNP) | VAF 155/336 reads (46%) | catalogued as rs759047469, COSV61192454; called by muse, mutect2, varscan2
- RYR2 | c.1614G>A p.A538= | Splice Region (SNP) | VAF 89/210 reads (42%) | catalogued as rs566885717, COSV63688605; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SACS | c.4502G>A p.R1501K | Missense Mutation (SNP) | VAF 185/391 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV101207499; called by muse, mutect2, varscan2
- SCEL | c.896G>A p.R299Q (on ENST00000349847 / NM_144777.3; = p.R279Q on NM_003843.4) | Missense Mutation (SNP) | VAF 91/216 reads (42%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.029); catalogued as rs149394221; called by muse, mutect2, varscan2
- SFMBT2 | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 127/228 reads (56%) | catalogued as COSV62811139; called by muse, mutect2, varscan2
- TNNT2 | c.886C>T p.R296C (on ENST00000236918; = p.R293C on NM_000364.4) | Missense Mutation (SNP) | VAF 247/533 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs367785431, CM031385, COSV52664595; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13B | c.4830G>C p.L1610F | Missense Mutation (SNP) | VAF 83/198 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as COSV62153497; called by muse, mutect2, varscan2
- WIPI2 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 227/482 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.394); catalogued as rs765007819, COSV56591964; called by muse, mutect2, varscan2
- ZFHX4 | c.9001G>A p.G3001R | Missense Mutation (SNP) | VAF 163/345 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as rs772582651, COSV50490189; called by muse, varscan2
- ZNF654 | c.1696C>T p.H566Y | Missense Mutation (SNP) | VAF 165/366 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1368258034; called by muse, mutect2, varscan2
- ATF6B | c.965A>G p.D322G | Missense Mutation (SNP) | VAF 141/305 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- CEP78 | c.137A>T p.N46I | Missense Mutation (SNP) | VAF 481/924 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.048); called by muse, mutect2
- CNTN1 | c.221T>C p.V74A | Missense Mutation (SNP) | VAF 284/285 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CRISPLD1 | c.1385A>C p.D462A | Missense Mutation (SNP) | VAF 198/405 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DDX11 | c.2572_2574dup p.A858dup (on ENST00000545668 / NM_152438.2; = p.L811dup on NM_004399.3) | In Frame Ins (INS) | VAF 215/759 reads (28%) | called by mutect2, pindel, varscan2
- FAAH2 | c.197A>G p.K66R | Missense Mutation (SNP) | VAF 119/119 reads (100%) | SIFT tolerated (0.31); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- FAM171A2 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 90/155 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GABRG3 | c.1073del p.P358Qfs*11 | Frame Shift Del (DEL) | VAF 146/337 reads (43%) | called by mutect2, pindel, varscan2
- HIPK1 | c.1259C>T p.T420I | Missense Mutation (SNP) | VAF 169/383 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- INSYN2B | c.557G>T p.C186F | Missense Mutation (SNP) | VAF 208/423 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- IRF1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 110/227 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- KCNJ3 | c.1072G>A p.V358M | Missense Mutation (SNP) | VAF 169/352 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- KIF15 | c.1481G>A p.R494K | Missense Mutation (SNP) | VAF 99/213 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- LRP1B | c.12811C>A p.P4271T | Missense Mutation (SNP) | VAF 112/249 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- MRAP2 | c.609C>A p.D203E | Missense Mutation (SNP) | VAF 121/264 reads (46%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); called by muse, mutect2
- MSH4 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 95/201 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NPIPB13 | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 42/408 reads (10%) | called by muse, mutect2
- PKDREJ | c.970T>A p.S324T | Missense Mutation (SNP) | VAF 178/403 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- PLCZ1 | c.983A>G p.K328R | Missense Mutation (SNP) | VAF 149/477 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPM1N | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 386/784 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIC1 | c.1273C>T p.Q425* | Nonsense Mutation (SNP) | VAF 146/317 reads (46%) | called by muse, mutect2, varscan2
- RYR3 | c.13978T>C p.S4660P (on ENST00000389232; = p.S4661P on NM_001036.6) | Missense Mutation (SNP) | VAF 173/328 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SI | c.2483_2485del p.G828del | In Frame Del (DEL) | VAF 40/232 reads (17%) | called by mutect2, pindel, varscan2
- SLC39A11 | c.48C>G p.F16L | Missense Mutation (SNP) | VAF 174/379 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC44A1 | c.1273T>C p.F425L | Missense Mutation (SNP) | VAF 119/235 reads (51%) | SIFT tolerated (0.65); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SPDL1 | c.517dup p.M173Nfs*14 | Frame Shift Ins (INS) | VAF 127/245 reads (52%) | called by mutect2, varscan2
- SSH2 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 154/338 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- TAX1BP1 | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 141/337 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TBC1D31 | c.1330C>A p.H444N | Missense Mutation (SNP) | VAF 162/315 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- USP17L1 | c.1160G>C p.R387T | Missense Mutation (SNP) | VAF 170/387 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZBTB10 | c.1302A>T p.Q434H | Missense Mutation (SNP) | VAF 214/448 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACACB | c.6288G>T p.V2096= | Silent (SNP) | VAF 201/648 reads (31%) | catalogued as COSV58148884, COSV58149646; called by muse, mutect2, varscan2
- ARHGAP25 | c.93G>A p.Q31= (on ENST00000409202 / NM_001007231.3; = p.Q24= on NM_014882.3) | Silent (SNP) | VAF 195/474 reads (41%) | catalogued as rs868045570, COSV54902218; called by muse, mutect2, varscan2
- BASP1 | c.333C>T p.P111= | Silent (SNP) | VAF 390/712 reads (55%) | catalogued as rs1237401196; called by muse, mutect2, varscan2
- C4BPA | c.252C>G p.G84= | Silent (SNP) | VAF 133/305 reads (44%) | called by muse, mutect2, varscan2
- CABP1 | c.786C>T p.T262= (on ENST00000316803 / NM_001033677.1; = p.T59= on NM_004276.5) | Silent (SNP) | VAF 523/773 reads (68%) | catalogued as rs564070934, COSV99974721; called by muse, mutect2, varscan2
- COL6A5 | c.967A>C p.R323= | Silent (SNP) | VAF 175/379 reads (46%) | called by muse, mutect2, varscan2
- DCAF12L1 | c.1086C>T p.I362= | Silent (SNP) | VAF 282/282 reads (100%) | called by muse, mutect2, varscan2
- DCP2 | c.819C>T p.F273= | Silent (SNP) | VAF 140/282 reads (50%) | called by muse, mutect2, varscan2
- GNA14 | c.384C>T p.I128= | Silent (SNP) | VAF 225/472 reads (48%) | called by muse, mutect2, varscan2
- HS3ST3A1 | c.624C>T p.D208= | Silent (SNP) | VAF 182/416 reads (44%) | catalogued as rs369654526; called by muse, varscan2
- IGHV3-53 | c.141C>T p.T47= | Silent (SNP) | VAF 87/264 reads (33%) | catalogued as rs781992517; called by muse, mutect2, varscan2
- IGHV3-66 | c.141C>T p.T47= | Silent (SNP) | VAF 148/621 reads (24%) | catalogued as rs782347421; called by muse, mutect2, varscan2
- KCNT1 | c.915C>A p.I305= (on ENST00000488444; = p.I324= on NM_020822.3) | Silent (SNP) | VAF 325/655 reads (50%) | called by muse, mutect2, varscan2
- PROB1 | c.42G>A p.P14= | Silent (SNP) | VAF 284/568 reads (50%) | called by muse, varscan2
- SEMA4F | c.883C>T p.L295= | Silent (SNP) | VAF 290/607 reads (48%) | catalogued as rs916922086; called by muse, mutect2, varscan2
- SLC7A14 | c.21G>A p.S7= | Silent (SNP) | VAF 155/324 reads (48%) | catalogued as COSV51577913; called by muse, mutect2, varscan2
- SOD1 | c.225A>G p.P75= | Silent (SNP) | VAF 141/319 reads (44%) | called by muse, mutect2, varscan2
- SORBS2 | c.2727G>A p.V909= (on ENST00000284776 / NM_021069.5; = p.V475= on NM_003603.6) | Silent (SNP) | VAF 136/315 reads (43%) | called by muse, mutect2, varscan2
- WSCD2 | c.513C>T p.G171= | Silent (SNP) | VAF 201/605 reads (33%) | catalogued as rs766850790, COSV54579301; called by muse, mutect2, varscan2
- XKR4 | c.267C>T p.G89= | Silent (SNP) | VAF 120/230 reads (52%) | called by muse, varscan2
- EFCAB5 | c.2738-4562G>A | Intron (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- OBSCN | c.6755-97C>T | Intron (SNP) | VAF 202/448 reads (45%) | catalogued as rs747944570; called by muse, mutect2, varscan2
- TMEM99 | n.800G>A | RNA (SNP) | VAF 218/416 reads (52%) | catalogued as rs528693743; called by muse, mutect2, varscan2
- ZNF83 | c.-166C>G | 5'UTR (SNP) | VAF 108/282 reads (38%) | called by muse, mutect2, varscan2
